Gene-level copy-number profile of tumor specimen TCGA-CC-A7IH-01A from TCGA case TCGA-CC-A7IH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 58.5 years (21,381 days).
Specimen TCGA-CC-A7IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.79d2cd96-4755-4305-a95d-3f6be4a162e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A7IH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/65ba9053-7831-467f-98ae-c8bb0c9a2295

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,380; copy number 2: 48,254; copy number 3: 4,259; copy number 4: 4,306; copy number 5: 621.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A7IH-01A-11D-A33B-01): tumor purity 0.88, ploidy 2.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 621 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:105,287,830–145,066,685, 585 genes, copy number 5 (broad region; genes not listed).
- chr11:72,080,331–72,674,591, 32 genes, copy number 5 (within-gene range 1–5): AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1.
- chr11:72,685,075–72,708,565, 4 genes, copy number 5: ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20.

Autosomal genes at a single copy (total copy number 1): 1,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
